Somatic mutation profile of tumor specimen TCGA-26-5135-01A (aliquot TCGA-26-5135-01A-01D-1486-08) from TCGA case TCGA-26-5135, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 72.5 years (26,490 days).
Specimen TCGA-26-5135-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6754f67c-6f79-4967-9fee-33244ea87240.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-26-5135-10A (Blood Derived Normal), aliquot TCGA-26-5135-10A-01D-1486-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6e8dd681-42b0-4569-91b0-2b7da64845fa

The open-access MAF lists 63 somatic variants for this specimen: 44 protein-altering or splice-affecting, 19 silent.
By variant classification: Missense Mutation 38, Silent 19, In Frame Del 2, Nonsense Mutation 2, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADCY5 | c.1879G>A p.E627K | Missense Mutation (SNP) | VAF 27/69 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.486); catalogued as rs1335271413, COSV59198452; called by muse, mutect2, varscan2
- ADD1 | c.2099G>A p.G700E | Missense Mutation (SNP) | VAF 64/164 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV53269522; called by muse, mutect2, varscan2
- CD22 | c.2514A>C p.E838D | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.07); catalogued as COSV50053822; called by muse, mutect2, varscan2
- CKM | c.287G>A p.R96H | Missense Mutation (SNP) | VAF 38/91 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.92); catalogued as rs780576836, COSV55532048; called by muse, mutect2, varscan2
- CTSG | c.286C>A p.R96S | Missense Mutation (SNP) | VAF 78/187 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.105); catalogued as COSV53535635, COSV99361719; called by muse, mutect2, varscan2
- CTTNBP2 | c.4045G>T p.V1349L | Missense Mutation (SNP) | VAF 92/304 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV50404555; called by muse, mutect2, varscan2
- DSG4 | c.473C>T p.S158L | Missense Mutation (SNP) | VAF 112/272 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.158); catalogued as rs369555342; called by muse, mutect2, varscan2
- FAM166C | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 73/206 reads (35%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs758184713, COSV61593389; called by muse, mutect2, varscan2
- FBXL12 | c.871G>A p.G291R | Missense Mutation (SNP) | VAF 43/90 reads (48%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.949); catalogued as COSV56114210, COSV99927996; called by muse, varscan2
- FCHO2 | c.1588C>T p.R530W | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs368140227; called by muse, mutect2, varscan2
- FOXN3 | c.908C>T p.A303V (on ENST00000261302; = p.A281V on NM_005197.4) | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as rs761828615, COSV54309241; called by muse, mutect2, varscan2
- GAPDH | c.874T>G p.S292A | Missense Mutation (SNP) | VAF 43/123 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.139); catalogued as COSV57521106; called by muse, mutect2, varscan2
- GGTLC1 | c.67T>C p.S23P | Missense Mutation (SNP) | VAF 56/151 reads (37%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.811); catalogued as COSV53848077; called by muse, mutect2, varscan2
- GON4L | c.944C>T p.T315M | Missense Mutation (SNP) | VAF 66/195 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs772087475, COSV55194541; called by muse, mutect2, varscan2
- HCN1 | c.2560C>T p.R854* | Nonsense Mutation (SNP) | VAF 84/203 reads (41%) | catalogued as rs534013981, COSV57513022, COSV57529311; called by muse, mutect2, varscan2
- HCN1 | c.1283G>A p.R428H | Missense Mutation (SNP) | VAF 89/247 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as rs1265198753, COSV57513032; called by muse, mutect2, varscan2
- HMGCLL1 | c.865A>G p.N289D | Missense Mutation (SNP) | VAF 33/129 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51445356; called by muse, mutect2, varscan2
- IGHD | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.1); PolyPhen benign (0.142); catalogued as rs369637149; called by muse, mutect2
- IGHJ6 | c.25G>A p.V9I | Missense Mutation (SNP) | VAF 54/130 reads (42%) | PolyPhen benign (0); catalogued as rs375601784; called by mutect2, varscan2
- KCNA10 | c.71A>T p.E24V | Missense Mutation (SNP) | VAF 29/72 reads (40%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.023); catalogued as COSV63904696; called by muse, mutect2, varscan2
- LRFN5 | c.973G>T p.G325W | Missense Mutation (SNP) | VAF 91/234 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV53257924; called by muse, mutect2, varscan2
- LRRC15 | c.1255C>T p.R419W | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.055); catalogued as rs373084418, COSV61650226; called by muse, mutect2, varscan2
- LRRC32 | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated (0.5); PolyPhen benign (0.232); catalogued as rs756729367, COSV52633176, COSV52634634; called by muse, mutect2, varscan2
- MSH4 | c.419G>A p.G140E | Missense Mutation (SNP) | VAF 93/216 reads (43%) | SIFT tolerated (0.37); PolyPhen benign (0.018); catalogued as rs1433238999, COSV54203566; called by muse, mutect2, varscan2
- NISCH | c.2449G>A p.A817T | Missense Mutation (SNP) | VAF 3/54 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.217); catalogued as COSV61902478; called by muse, mutect2
- OR2L13 | c.362G>A p.R121H | Missense Mutation (SNP) | VAF 157/428 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as rs765402005, COSV63547613; called by muse, mutect2, varscan2
- PDE3A | c.1270C>T p.R424C | Missense Mutation (SNP) | VAF 52/140 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as rs532896888, COSV62973769; called by muse, mutect2, varscan2
- PFKFB4 | c.1052G>A p.R351Q | Missense Mutation (SNP) | VAF 38/102 reads (37%) | PolyPhen possibly damaging (0.904); catalogued as rs1337253903, COSV51681063; called by muse, mutect2, varscan2
- RXFP1 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 103/234 reads (44%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs368431235; called by muse, mutect2, varscan2
- SIPA1L3 | c.124C>T p.Q42* | Nonsense Mutation (SNP) | VAF 16/49 reads (33%) | catalogued as COSV55914944; called by muse, mutect2, varscan2
- SKIV2L | c.3236G>A p.R1079Q | Missense Mutation (SNP) | VAF 65/186 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); catalogued as COSV61713053; called by muse, mutect2
- SLCO5A1 | c.1177G>A p.D393N | Missense Mutation (SNP) | VAF 56/139 reads (40%) | SIFT tolerated (0.19); PolyPhen benign (0.257); catalogued as rs749034973, COSV52658738; called by muse, mutect2, varscan2
- SLIT3 | c.3526G>A p.V1176I | Missense Mutation (SNP) | VAF 68/171 reads (40%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV60609144; called by muse, mutect2, varscan2
- SPTA1 | c.4823G>A p.R1608H | Missense Mutation (SNP) | VAF 103/257 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); catalogued as rs781244377, COSV63753851, COSV63759960; called by muse, mutect2, varscan2
- SUPT6H | c.2229G>A p.K743= | Splice Region (SNP) | VAF 21/43 reads (49%) | catalogued as COSV58927642; called by muse, mutect2, varscan2
- SVIL | c.6278-1G>A p.X2093_splice (on ENST00000355867 / NM_021738.3; = p.X1667_splice on NM_003174.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 53/89 reads (60%) | catalogued as COSV63448544; called by muse, mutect2, varscan2
- TENM3 | c.5717G>A p.R1906Q | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.953); catalogued as rs746186070, COSV69304772; called by muse, mutect2, varscan2
- TRIM33 | c.1319G>A p.R440H | Missense Mutation (SNP) | VAF 86/218 reads (39%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as rs755058963, COSV61822813; called by muse, mutect2, varscan2
- UGT3A1 | c.1139G>A p.R380H | Missense Mutation (SNP) | VAF 89/240 reads (37%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as rs375679556; called by muse, mutect2, varscan2
- VAMP5 | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 60/172 reads (35%) | SIFT tolerated (0.69); PolyPhen benign (0.013); catalogued as rs769759669, COSV60498396; called by muse, mutect2, varscan2
- ZNF285 | c.1240G>A p.V414I | Missense Mutation (SNP) | VAF 62/149 reads (42%) | SIFT tolerated (0.42); PolyPhen benign (0.036); catalogued as rs766367743, COSV58409152; called by muse, mutect2, varscan2
- ZNF57 | c.1448A>G p.K483R | Missense Mutation (SNP) | VAF 76/173 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1322979948, COSV60983570; called by muse, mutect2, varscan2
- PDGFRA | c.722_751del p.E241_P250del | In Frame Del (DEL) | VAF 796/4396 reads (18%) | called by mutect2, pindel
- TAF4 | c.2990_2995del p.A997_M999delinsV | In Frame Del (DEL) | VAF 67/235 reads (29%) | called by mutect2, pindel, varscan2
- ADAM7 | c.489G>A p.P163= | Silent (SNP) | VAF 88/261 reads (34%) | catalogued as rs776521318, COSV51540515; called by muse, mutect2, varscan2
- AGMO | c.978C>T p.P326= | Silent (SNP) | VAF 74/262 reads (28%) | catalogued as rs1474077616, COSV61113438; called by muse, mutect2, varscan2
- ATF7IP | c.3501G>A p.K1167= | Silent (SNP) | VAF 42/112 reads (38%) | catalogued as COSV53771369; called by muse, mutect2, varscan2
- BAHD1 | c.2229C>T p.D743= | Silent (SNP) | VAF 160/347 reads (46%) | catalogued as COSV60378864; called by muse, mutect2, varscan2
- CHST5 | c.258C>T p.P86= | Silent (SNP) | VAF 33/74 reads (45%) | catalogued as rs753342076, COSV60339473; called by muse, mutect2, varscan2
- CRTC2 | c.246C>T p.A82= | Silent (SNP) | VAF 34/114 reads (30%) | catalogued as rs372355568; called by muse, mutect2, varscan2
- EFNB2 | c.24G>T p.V8= | Silent (SNP) | VAF 38/100 reads (38%) | catalogued as COSV55364949; called by muse, mutect2, varscan2
- GCC1 | c.1800C>T p.D600= | Silent (SNP) | VAF 55/197 reads (28%) | catalogued as COSV58462707; called by muse, mutect2, varscan2
- HCRTR1 | c.60G>A p.P20= | Silent (SNP) | VAF 88/237 reads (37%) | catalogued as rs142288232; called by muse, mutect2, varscan2
- HLA-G | c.765G>C p.V255= | Silent (SNP) | VAF 83/248 reads (33%) | catalogued as COSV64405885; called by muse, mutect2, varscan2
- IL32 | c.582C>T p.F194= (on ENST00000396890 / NM_001308078.4; = p.F148= on NM_004221.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 79/226 reads (35%) | catalogued as COSV50404692; called by muse, varscan2
- JAK3 | c.1992G>A p.P664= | Silent (SNP) | VAF 55/125 reads (44%) | catalogued as rs200499852; called by muse, mutect2, varscan2
- MATN4 | c.1824G>A p.T608= (on ENST00000372754; = p.T567= on NM_003833.4) | Silent (SNP) | VAF 16/49 reads (33%) | catalogued as COSV61351461; called by muse, mutect2, varscan2
- PIK3CG | c.573C>T p.R191= | Silent (SNP) | VAF 50/175 reads (29%) | catalogued as rs145944814, COSV63248832; called by muse, mutect2, varscan2
- PSMD2 | c.1338T>C p.L446= | Silent (SNP) | VAF 83/211 reads (39%) | catalogued as rs1215220782, COSV59529963; called by muse, mutect2, varscan2
- PTCD2 | c.729C>T p.F243= | Silent (SNP) | VAF 48/123 reads (39%) | catalogued as rs777210186, COSV57337975; called by muse, mutect2, varscan2
- SLC6A19 | c.999C>T p.Y333= | Silent (SNP) | VAF 42/92 reads (46%) | catalogued as rs967212443, COSV58671538; called by muse, mutect2, varscan2
- SRSF3 | c.168C>T p.P56= | Silent (SNP) | VAF 49/173 reads (28%) | catalogued as COSV59671164; called by muse, mutect2, varscan2
- STYXL2 | c.2028G>A p.T676= | Silent (SNP) | VAF 24/64 reads (38%) | catalogued as rs376593703; called by muse, mutect2, varscan2
